Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2J7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2J7-06A (Metastatic).

DIAGNOSIS

Patient ID – Sample ID

Diagnostic Discrepancy		X
IIHAA Discrepancy		X

(A) LEFT PARASCAPULAR REGION, ELLIPSE:
METASTATIC MELANOMA IN SOFT TISSUE IN ONE OF TWO LYMPH NODES.
THE LARGEST TUMOR SIZE 13.0 MM.
EXTRACAPSULAR EXTENSION PRESENT.

(B) ADDITIONAL SUPERIOR MEDIAL MARGIN:
Adipose tissue and skeletal muscle without melanoma.

100-0-3

Melanoma, Nos 8720/3

Site: lymph node, Nos C779

for 7/24/11

Entire report and diagnosis completed by MD

GROSS DESCRIPTION

(A) EXCISION OF SUBCUTANEOUS NODULE, LEFT PARASCAPULAR REGION, LONG LATERAL, SHORT SUPERIOR – An ellipse of skin and underlying subcutaneous tissue that measures 5.2 x 3.8 x 3.5 cm overall. An ellipse of tan skin (4.0 x 1.7 cm) is attached and designated with a short stitch denoting superior and long stitch denoting the lateral aspects.

A 3.0 x 2.0 x 2.0 cm multilobulated tan to dusky gray-brown tumor is present. The tumor is less than 0.1 cm from the nearest inferior margin and 1.7 cm from the skin surface.

The remaining tumor and sections of normal skin and subcutaneous tissue are submitted for tumor bank.

INK CODE: Superior-blue, inferior-orange.

SECTION CODE: A1, tumor with nearest inferior margin; A2, tumor with superior and inferior margin.

(B) ADDITIONAL SUPERIOR MEDIAL MARGIN, SUTURE EQUALS TRUE MARGIN – A 2.8 x 2.0 x 0.8 cm irregular fragment of yellow lobulated adipose tissue marked with a single suture denoting the true margin.

Sections reveal focally hemorrhagic adipose tissue with no identifiable tumor.

INK CODE: Black = true margin.

SECTION CODE: B1-B4, entire margin.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file a00360e7-b831-468c-b1cf-a35d375e5859 (TCGA-D3-A2J7.11EC83A8-0B02-4D96-B795-66317F21B3FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).